Somatic mutation profile of tumor specimen aa0f5b40-3290-4255-8f4d-f45d4e (aliquot aa0f5b40-3290-4255-8f4d-f45d4e_D6) from CPTAC case 09CO008, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen aa0f5b40-3290-4255-8f4d-f45d4e: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5290a7e-f4ff-491d-87ff-e07c1a85133d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 02345909-96ed-4f40-a623-7b95be (Blood Derived Normal), aliquot 02345909-96ed-4f40-a623-7b95be_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61819898-b595-4272-ba58-ec1eea051880

The open-access MAF lists 118 somatic variants for this specimen: 86 protein-altering or splice-affecting, 22 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 22, Intron 7, Nonsense Mutation 6, Frame Shift Del 3, Frame Shift Ins 2, RNA 1, Splice Site 1, In Frame Del 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2426del p.N809Ifs*11 | Frame Shift Del (DEL) | VAF 190/700 reads (27%) | catalogued as rs1114167573; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- APC | c.4463del p.L1488Yfs*19 | Frame Shift Del (DEL) | VAF 92/370 reads (25%) | catalogued as rs1114167577, COSV57389473; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.332T>A p.L111Q | Missense Mutation (SNP) | VAF 94/201 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519997, CX942126, COSV52676090, COSV52699193, COSV52985195; ClinVar: likely pathogenic / uncertain significance; called by mutect2, varscan2
- ACHE | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs749032132, COSV53815758; called by muse, mutect2, varscan2
- ACOD1 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 111/356 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs767323284, COSV66291594; called by muse, mutect2, varscan2
- ANKLE1 | c.1489C>T p.R497W (on ENST00000394458; = p.R443W on NM_152363.6) | Missense Mutation (SNP) | VAF 95/265 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748154981, COSV104421581; called by muse, mutect2, varscan2
- ANKRD34C | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 158/334 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs879518409; called by muse, mutect2, varscan2
- ANKRD35 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 26/191 reads (14%) | catalogued as rs368079050; called by muse, mutect2, varscan2
- ASH2L | c.1453G>A p.V485I | Missense Mutation (SNP) | VAF 98/192 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs767918385, COSV51699794; called by muse, mutect2, varscan2
- ATP7A | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 232/404 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV58450678; called by muse, mutect2, varscan2
- BRINP2 | c.1020C>A p.F340L | Missense Mutation (SNP) | VAF 60/464 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV64175589; called by mutect2, varscan2
- CACNA1E | c.4648G>A p.V1550M | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773509097, COSV100705928; called by muse, mutect2, varscan2
- CLGN | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 114/329 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765901430, COSV57777208; called by muse, mutect2, varscan2
- CRTAC1 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 102/269 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs368780856; called by muse, mutect2, varscan2
- CUL3 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 65/274 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs757584952; called by muse, mutect2, varscan2
- DLL4 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 34/556 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs765240965; called by muse, mutect2
- EFHB | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 106/428 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs142916632; called by muse, mutect2, varscan2
- ENPEP | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 91/360 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs544907084, COSV54453278; called by muse, mutect2, varscan2
- EPPK1 | c.3742G>A p.V1248M | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs782562924; called by muse, mutect2, varscan2
- FBN2 | c.4216T>A p.C1406S | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM152790; called by muse, mutect2
- GHSR | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 284/1066 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV53839745; called by muse, mutect2, varscan2
- GPR37 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 105/374 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV58258261, COSV58258868; called by mutect2, varscan2
- GRIK1 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 80/163 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539327767, COSV58710129; called by muse, mutect2, varscan2
- HAND2 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV64017899; called by muse, mutect2
- IFIH1 | c.1449G>C p.Q483H | Missense Mutation (SNP) | VAF 132/522 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753216541; called by muse, mutect2, varscan2
- KRT77 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 79/293 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as rs757643596, COSV100526881; called by muse, mutect2, varscan2
- LTO1 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 55/366 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs759989062, COSV54162649; called by muse, mutect2, varscan2
- NAA15 | c.1882_1884del p.K628del | In Frame Del (DEL) | VAF 31/120 reads (26%) | catalogued as rs748893271; called by pindel, varscan2
- NFASC | c.1996G>T p.E666* (on ENST00000339876 / NM_001378329.1; = p.E662* on NM_015090.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/470 reads (6%) | catalogued as COSV99046031; called by muse, mutect2
- NRXN1 | c.3202G>A p.D1068N | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs200722697, COSV58468372; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP2R5B | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751632297, COSV51210063; called by muse, mutect2, varscan2
- PREX2 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs201372935, COSV99906079; called by muse, mutect2, varscan2
- PSMB8 | c.304C>T p.R102W (on ENST00000374882 / NM_148919.4; = p.R98W on NM_004159.5) | Missense Mutation (SNP) | VAF 411/997 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs1402857650, COSV62754215; called by muse, mutect2, varscan2
- PTPRM | c.2816G>A p.R939Q | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs780055249, COSV59843929; called by muse, mutect2, varscan2
- RGL3 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 136/542 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439502542; called by muse, mutect2, varscan2
- RIMS2 | c.1830G>C p.M610I (on ENST00000666250 / NM_001348490.2; = p.M418I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as COSV51739666; called by muse, mutect2, varscan2
- SP1 | c.2254G>T p.E752* (on ENST00000327443 / NM_138473.3; = p.E745* on NM_003109.1) | Nonsense Mutation (SNP) | VAF 55/660 reads (8%) | catalogued as COSV100540649; called by muse, mutect2
- SYNE1 | c.3896C>T p.A1299V (on ENST00000367255 / NM_182961.4; = p.A1306V on NM_033071.3) | Missense Mutation (SNP) | VAF 82/710 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as rs1184329555, COSV99553822; called by muse, mutect2, varscan2
- SYNM | c.4664A>G p.N1555S (on ENST00000336292 / NM_145728.3; = p.N1243S on NM_015286.6) | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as rs782738335; called by muse, mutect2, varscan2
- TENM2 | c.5717G>A p.R1906H (on ENST00000518659 / NM_001122679.2; = p.R1667H on NM_001080428.3) | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs574223894, COSV69130385; called by muse, mutect2
- TTN | c.8099C>A p.A2700D (on ENST00000591111; = p.A2654D on NM_003319.4) | Missense Mutation (SNP) | VAF 158/609 reads (26%) | PolyPhen probably damaging (0.999); catalogued as rs1381263123; called by muse, mutect2, varscan2
- TUBGCP3 | c.2104C>T p.H702Y | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1566537615, COSV56185168; called by muse, varscan2
- UBA7 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs983604974; called by muse, mutect2
- USP9X | c.5863C>T p.R1955* | Nonsense Mutation (SNP) | VAF 129/210 reads (61%) | catalogued as COSV100198624; called by muse, mutect2, varscan2
- ZFPM2 | c.1752C>G p.F584L | Missense Mutation (SNP) | VAF 66/1343 reads (5%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.97); catalogued as COSV65872663; called by muse, mutect2
- ZNF829 | c.630dup p.P211Tfs*3 | Frame Shift Ins (INS) | VAF 75/304 reads (25%) | catalogued as rs752311498; called by mutect2, pindel, varscan2
- ZNRF4 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 38/361 reads (11%) | catalogued as rs1393054722; called by muse, mutect2, varscan2
- BRINP2 | c.1019T>A p.F340Y | Missense Mutation (SNP) | VAF 64/506 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- CYP2A6 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 20/325 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.226); called by muse, mutect2
- DCC | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 142/368 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DMPK | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 116/341 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- FAM155B | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 117/182 reads (64%) | called by muse, mutect2, varscan2
- FAT4 | c.13520T>C p.V4507A | Missense Mutation (SNP) | VAF 58/530 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FBXW5 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 160/447 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FRAS1 | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.25); called by muse, mutect2
- GCKR | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 60/292 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- GRIA4 | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 78/215 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- GRIK2 | c.657A>T p.K219N | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GYG2 | c.1187C>G p.S396C | Missense Mutation (SNP) | VAF 84/142 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- HNRNPAB | c.287T>G p.V96G | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- JMY | c.1348G>C p.A450P | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KLK4 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 89/811 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA5 | c.1771C>A p.P591T | Missense Mutation (SNP) | VAF 198/322 reads (61%) | SIFT tolerated (0.36); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NKTR | c.242-1G>A p.X81_splice | Splice Site (SNP) | VAF 38/174 reads (22%) | called by muse, mutect2, varscan2
- NUP88 | c.1324T>A p.S442T | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- PADI1 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- PHF20L1 | c.790A>G p.K264E | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PIKFYVE | c.2299C>T p.H767Y | Missense Mutation (SNP) | VAF 49/459 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- POLR1F | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- PPT2 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PTGS2 | c.329T>G p.I110S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- RAB25 | c.50T>G p.L17R | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGS8 | c.131G>C p.R44T (on ENST00000367556 / NM_001369564.2; = p.R62T on NM_033345.3) | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- RNF213 | c.2543G>C p.C848S | Missense Mutation (SNP) | VAF 46/859 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.172); called by muse, mutect2
- RPS3 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- SLC15A1 | c.116T>G p.L39R | Missense Mutation (SNP) | VAF 91/290 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC6A5 | c.2237A>T p.E746V | Missense Mutation (SNP) | VAF 104/804 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- SYNE1 | c.7004C>T p.T2335I (on ENST00000367255 / NM_182961.4; = p.T2342I on NM_033071.3) | Missense Mutation (SNP) | VAF 189/456 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SYT16 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TINF2 | c.1345A>G p.R449G | Missense Mutation (SNP) | VAF 227/683 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRIM51 | c.440del p.L147Yfs*12 | Frame Shift Del (DEL) | VAF 60/211 reads (28%) | called by mutect2, pindel, varscan2
- TSTD1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 18/311 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.125); called by muse, mutect2
- TTN | c.40265G>T p.W13422L (on ENST00000591111; = p.W5998L on NM_003319.4) | Missense Mutation (SNP) | VAF 37/339 reads (11%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TUT1 | c.1615dup p.L539Pfs*8 | Frame Shift Ins (INS) | VAF 98/440 reads (22%) | called by mutect2, pindel, varscan2
- WDFY4 | c.3140G>T p.S1047I | Missense Mutation (SNP) | VAF 78/356 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by mutect2, varscan2
- ZNFX1 | c.449A>C p.E150A | Missense Mutation (SNP) | VAF 19/682 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2
- ABCA10 | c.1728C>T p.D576= | Silent (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- CFH | c.2181A>G p.G727= | Silent (SNP) | VAF 116/637 reads (18%) | catalogued as rs779196518; called by muse, mutect2, varscan2
- DISP2 | c.3555G>T p.L1185= | Silent (SNP) | VAF 73/456 reads (16%) | called by muse, mutect2, varscan2
- FAM160A1 | c.2628C>T p.I876= | Silent (SNP) | VAF 98/311 reads (32%) | catalogued as rs1028660561; called by muse, mutect2, varscan2
- FAM47B | c.93G>A p.A31= | Silent (SNP) | VAF 131/235 reads (56%) | catalogued as COSV61454351; called by muse, mutect2, varscan2
- FAM83B | c.2151G>A p.L717= | Silent (SNP) | VAF 12/246 reads (5%) | called by muse, mutect2
- GMPPA | c.1206G>T p.S402= | Silent (SNP) | VAF 66/273 reads (24%) | catalogued as rs763262265; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR37 | c.1290C>T p.T430= | Silent (SNP) | VAF 70/330 reads (21%) | catalogued as rs1243531468; called by muse, mutect2, varscan2
- H1-2 | c.441G>A p.P147= | Silent (SNP) | VAF 40/375 reads (11%) | catalogued as COSV59192137, COSV59193598; called by muse, mutect2, varscan2
- KIAA0825 | c.1092C>T p.D364= | Silent (SNP) | VAF 57/157 reads (36%) | catalogued as rs566161789; called by muse, mutect2, varscan2
- MCF2L | c.747G>A p.Q249= (on ENST00000375608; = p.Q217= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 72/204 reads (35%) | called by muse, mutect2, varscan2
- NBPF14 | c.3603A>G p.R1201= | Silent (SNP) | VAF 44/238 reads (18%) | called by muse, mutect2, varscan2
- NLGN4Y | c.1173G>A p.T391= | Silent (SNP) | VAF 679/964 reads (70%) | catalogued as COSV100196299; called by muse, mutect2, varscan2
- NXN | c.414C>T p.L138= | Silent (SNP) | VAF 73/190 reads (38%) | catalogued as rs369883008; called by muse, mutect2, varscan2
- OR1L8 | c.654T>A p.S218= | Silent (SNP) | VAF 29/326 reads (9%) | called by muse, mutect2
- OR2G3 | c.297G>A p.A99= | Silent (SNP) | VAF 283/669 reads (42%) | catalogued as rs145338640, COSV60682358, COSV60682510; called by muse, mutect2, varscan2
- PCDHB15 | c.1590C>T p.R530= | Silent (SNP) | VAF 436/1350 reads (32%) | called by muse, mutect2
- PLEKHF1 | c.66C>T p.F22= | Silent (SNP) | VAF 82/316 reads (26%) | catalogued as rs749347941; called by muse, mutect2, varscan2
- PWWP2B | c.1611G>A p.S537= | Silent (SNP) | VAF 180/523 reads (34%) | catalogued as rs759062631, COSV59452175; called by muse, mutect2, varscan2
- VEGFD | c.915G>A p.K305= | Silent (SNP) | VAF 60/102 reads (59%) | catalogued as rs750123121; called by muse, mutect2, varscan2
- ZNF34 | c.111C>T p.F37= | Silent (SNP) | VAF 28/304 reads (9%) | catalogued as rs200323832; called by muse, mutect2
- ZNF713 | c.1152C>G p.P384= (on ENST00000633730 / NM_001366796.2; = p.P397= on NM_182633.3) | Silent (SNP) | VAF 34/322 reads (11%) | called by muse, mutect2
- AC093642.3 | n.2693G>A | RNA (SNP) | VAF 82/552 reads (15%) | called by muse, varscan2
- DOCK8 | c.741+119A>G | Intron (SNP) | VAF 18/647 reads (3%) | catalogued as rs1364783107; called by muse, mutect2
- ELMO2 | c.79-17_79-16insCC | Intron (INS) | VAF 50/370 reads (14%) | catalogued as rs1484304360; called by mutect2, pindel, varscan2
- EPN1 | c.-101-829G>A | Intron (SNP) | VAF 41/128 reads (32%) | called by muse, mutect2, varscan2
- FAM89B | chr11:65572489 C>T | 5'Flank (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- FN1 | c.6441+36C>A | Intron (SNP) | VAF 65/453 reads (14%) | called by muse, mutect2, varscan2
- GATA1 | c.*90C>A | 3'UTR (SNP) | VAF 31/131 reads (24%) | called by muse, mutect2, varscan2
- SCYL2 | c.1929+13T>A | Intron (SNP) | VAF 28/231 reads (12%) | called by muse, mutect2, varscan2
- TCF7L2 | c.1442+653G>A | Intron (SNP) | VAF 69/204 reads (34%) | catalogued as COSV53337859; called by muse, mutect2, varscan2
- XXYLT1 | c.505-20971G>A | Intron (SNP) | VAF 45/167 reads (27%) | called by muse, mutect2, varscan2
